Surgical pathology report (de-identified scan), TCGA case TCGA-G6-A8L6, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G6-A8L6-01A (Primary Tumor).

[page 1 of 2]
ICD0-3
Carcinoma, clear cell 8310/3
Site @ Kidney NOS C64.9
JW 11/24/13

SPECIMENS:

A. LEFT KIDNEY

SPECIMEN(S):

A. LEFT KIDNEY

DIAGNOSIS:

A. KIDNEY, LEFT, RESECTION:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE
- FUHRMAN NUCLEAR GRADE 2-3
- TUMOR SIZE: 9.7 CM
- TUMOR EXTENT: TUMOR LIMITED TO THE KIDNEY
- NO VASCULAR INVASION IS IDENTIFIED
- SURGICAL MARGIN IS NEGATIVE
- ADRENAL GLAND, NEGATIVE FOR METASTASIS

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: LEFT KIDNEY

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Left

Tumor Site: Middle pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 9.7cm

Additional dimensions: 7.8cm x 5.7cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Clear cell renal cell carcinoma 8310/3

Histologic Grade (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 2a N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pT2a: Tumor more than 7 cm but less than or equal to 10 cm in greatest dimension, limited to the kidney

GROSS DESCRIPTION:

A. LEFT KIDNEY

Received fresh labeled with patient's identification and "left kidney" is a 815 g kidney with attached perinephric fat, 21.5 x 12 x 7.8 cm. The kidney is 14.8 x 10.3 x 6.2 cm. Extending from the renal pelvis are a ureter (2.3 cm in length and 0.5 cm in diameter), renal vein (0.8 cm in length and 3.1 cm in diameter), and renal artery (0.5 cm in length and 0.5 cm in diameter). The tumor does not extend into the ureter, artery, or vein and is not present at the resection margin. The kidney is inked black and is bivalved revealing a 9.7 x 7.8 x 5.7 cm well-circumscribed, solid, golden orange mass with areas of hemorrhage and possible fibrosis located in the mid kidney. It pushes on the anterior and lateral capsule but does not grossly appear to invade through the capsule. The uninvolved renal parenchyma is tan-brown with well defined cortical medullary junction and orderly cortical striations and medullary rays. The pelvis and calyces appear smooth. There is a 6.2 x 4.1 x 0.8 cm adrenal gland; it is unremarkable. No lymph nodes or stones are identified. A photograph is taken and tissue is procured; representatively submitted:

[page 2 of 2]
A1: shave of ureter margin
A2: shave of vasculature margins
A3-A4: mass and relationship to perinephric fat
A5-A8: mass in relationship to pelvis and normal appearing parenchyma
A9-A10: mass in relationship to capsule
A11: normal appearing parenchyma
A12: adrenal gland

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

Gross Dictation: ,
Microscopic/Diagnostic Dictation: Pathologist
Final Review: Pathologist
Final: Pathologist

Criteria	11/14/13	Yes	No

Source: NCI Genomic Data Commons file 8bb3785e-6ffd-4f08-bf69-6b5f65a63ea4 (TCGA-G6-A8L6.851138C1-3B4F-4D74-B938-279BC4F5B950.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).